Somatic mutation profile of tumor specimen TCGA-CQ-6220-01A (aliquot TCGA-CQ-6220-01A-11D-1912-08) from TCGA case TCGA-CQ-6220, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 69.4 years (25,366 days).
Specimen TCGA-CQ-6220-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7cc6fdc0-3692-4127-b2b4-af636cf229d1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CQ-6220-10A (Blood Derived Normal), aliquot TCGA-CQ-6220-10A-01D-1912-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bdafd83a-1dff-461f-8553-3b16fc4a16e7

The open-access MAF lists 110 somatic variants for this specimen: 83 protein-altering or splice-affecting, 26 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 73, Silent 26, Nonsense Mutation 5, Splice Region 2, RNA 1, Nonstop Mutation 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.124A>C p.N42H | Missense Mutation (SNP) | VAF 87/155 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58690934, COSV58703253, COSV58725223; called by muse, mutect2, varscan2
- TP53 | c.838A>G p.R280G | Missense Mutation (SNP) | VAF 18/31 reads (58%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs753660142, COSV52662754, COSV52708728, COSV52851287; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCB6 | c.1957G>C p.D653H | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.697); catalogued as COSV99202476; called by muse, mutect2, varscan2
- ACTA2 | c.247G>A p.D83N | Missense Mutation (SNP) | VAF 30/187 reads (16%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.313); catalogued as rs794728023, COSV99827214; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AHNAK | c.15466G>C p.E5156Q | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV99948913; called by muse, mutect2, varscan2
- AIFM1 | c.532G>C p.E178Q | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV99781315; called by muse, mutect2, varscan2
- ALK | c.2074G>A p.G692R | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373846404, COSV66585352; ClinVar: uncertain significance; called by mutect2, varscan2
- ANKLE2 | c.2209G>C p.D737H | Missense Mutation (SNP) | VAF 9/147 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.907); catalogued as COSV61708103; called by muse, mutect2
- APOBEC3H | c.200G>A p.G67E | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.241); catalogued as COSV100818863; called by muse, mutect2, varscan2
- ARHGAP32 | c.5464G>A p.E1822K (on ENST00000310343 / NM_001378025.1; = p.E1473K on NM_014715.4) | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.278); catalogued as rs138669502, COSV100088702, COSV59854737; called by muse, mutect2, varscan2
- ARV1 | c.504G>A p.M168I | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV100048552, COSV59617387; called by muse, mutect2, varscan2
- ARV1 | c.505A>C p.T169P | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.269); catalogued as COSV100048556; called by muse, mutect2, varscan2
- BCAS3 | c.1721C>T p.S574L (on ENST00000390652 / NM_001353144.2; = p.S559L on NM_017679.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.979); catalogued as rs959545152, COSV66783081; called by muse, mutect2, varscan2
- CABYR | c.140A>G p.Y47C | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as COSV100510132; called by muse, mutect2, varscan2
- CACNA2D4 | c.1267T>A p.C423S | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.076); catalogued as COSV99766250; called by muse, mutect2, varscan2
- CALHM4 | c.697G>C p.E233Q (on ENST00000368596 / NM_001366078.1; = p.E47Q on NM_153036.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT tolerated (0.59); PolyPhen benign (0.106); catalogued as COSV100888893; called by muse, mutect2, varscan2
- CASP8 | c.212G>C p.R71T | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV51846504, COSV99965286, COSV99965729; called by muse, mutect2, varscan2
- CENPW | c.124T>C p.L42= | Splice Region (SNP) | VAF 21/108 reads (19%) | catalogued as rs758426987, COSV100851383; called by muse, mutect2, varscan2
- CNGA4 | c.359C>T p.A120V | Missense Mutation (SNP) | VAF 60/213 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV101171843; called by muse, mutect2, varscan2
- COL4A2 | c.1502C>A p.P501H | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.866); catalogued as COSV64632410; called by muse, mutect2
- CPAMD8 | c.4966C>T p.R1656* (on ENST00000651564; = p.R1609* on NM_015692.5) | Nonsense Mutation (SNP) | VAF 7/56 reads (13%) | catalogued as rs753438460, COSV101488558; called by muse, mutect2, varscan2
- CPSF6 | c.925C>T p.P309S | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT tolerated (0.84); PolyPhen benign (0.094); catalogued as COSV99879613; called by muse, mutect2, varscan2
- CS | c.218G>C p.R73T | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV100673295; called by muse, mutect2, varscan2
- CSMD3 | c.10158A>T p.Q3386H (on ENST00000297405 / NM_001363185.1; = p.Q3217H on NM_052900.3) | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV52299752; called by muse, mutect2, varscan2
- CSMD3 | c.3895G>C p.G1299R (on ENST00000297405 / NM_001363185.1; = p.G1195R on NM_052900.3) | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52328735, COSV99843199; called by muse, mutect2
- CTDSPL2 | c.1396G>C p.D466H | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99527146; called by muse, mutect2
- DNAJC14 | c.1315G>A p.E439K | Missense Mutation (SNP) | VAF 12/206 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as rs1565690045, COSV100423681; called by muse, mutect2
- DYNC1H1 | c.11688G>T p.V3896= | Splice Region (SNP) | VAF 15/103 reads (15%) | catalogued as COSV64143306; called by muse, mutect2, varscan2
- ENPP2 | c.504C>G p.I168M | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.149); catalogued as COSV99309054; called by muse, mutect2, varscan2
- EP400 | c.5582C>T p.S1861L | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); catalogued as COSV100201943; called by muse, mutect2, varscan2
- ERMARD | c.202G>A p.V68M | Missense Mutation (SNP) | VAF 17/157 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs1211412748, COSV100824886, COSV64650157; called by muse, mutect2, varscan2
- ESF1 | c.71A>C p.E24A | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99176471; called by muse, mutect2, varscan2
- EXOC4 | c.2254G>C p.V752L | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV99555064; called by muse, mutect2, varscan2
- EXT1 | c.506A>G p.Q169R | Missense Mutation (SNP) | VAF 30/224 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV100984114; called by muse, mutect2, varscan2
- FAM135B | c.1934G>A p.S645N | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV99426287; called by muse, mutect2, varscan2
- FAT3 | c.607C>T p.L203F | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as rs1038730005, COSV99968991; called by muse, mutect2, varscan2
- FCHSD2 | c.1498G>A p.E500K | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); catalogued as COSV100238894; called by muse, mutect2, varscan2
- GABRA1 | c.71G>T p.R24I | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV99196172; called by muse, mutect2, varscan2
- GABRB3 | c.646C>T p.H216Y | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100161158; called by muse, mutect2, varscan2
- GABRR2 | c.317A>G p.H106R | Missense Mutation (SNP) | VAF 42/160 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV101299015; called by muse, mutect2, varscan2
- GC | c.763G>A p.A255T | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as COSV99910018; called by muse, mutect2, varscan2
- GDPD1 | c.812G>A p.R271Q | Missense Mutation (SNP) | VAF 50/116 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745893247, COSV52385715; called by muse, mutect2, varscan2
- GGT5 | c.1559C>T p.P520L | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV99571786; called by muse, mutect2
- GRM7 | c.590G>A p.R197H | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63151796; called by muse, mutect2, varscan2
- GUCY2D | c.2177C>T p.A726V | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.284); catalogued as COSV99644203; called by muse, mutect2, varscan2
- HAP1 | c.1654G>T p.E552* (on ENST00000310778 / NM_001367460.1; = p.E500* on NM_177977.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 45/367 reads (12%) | catalogued as rs782082127, COSV100169890, COSV57878098; called by muse, mutect2, varscan2
- HELZ2 | c.2492G>C p.C831S (on ENST00000467148 / NM_001037335.2; = p.C262S on NM_033405.3) | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100915660; called by muse, mutect2
- KIF21B | c.2761C>T p.R921* | Nonsense Mutation (SNP) | VAF 7/50 reads (14%) | catalogued as rs768350530, COSV59768400; called by muse, mutect2, varscan2
- KYNU | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as COSV99933720; called by muse, mutect2, varscan2
- LRP2 | c.12421G>T p.V4141L | Missense Mutation (SNP) | VAF 67/267 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV99789745; called by muse, mutect2, varscan2
- MATN2 | c.2302G>A p.D768N | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1457258428, COSV99646867; called by muse, mutect2
- MYH6 | c.4150C>T p.R1384W | Missense Mutation (SNP) | VAF 49/145 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763926580, COSV100676873; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NCAPG2 | c.874C>T p.H292Y | Missense Mutation (SNP) | VAF 20/151 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.075); catalogued as COSV99317452; called by muse, mutect2, varscan2
- NEB | c.6191A>G p.Y2064C | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51428398; called by muse, mutect2, varscan2
- NLRP2 | c.871G>C p.D291H | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54751988; called by muse, mutect2
- NUMB | c.1363C>T p.Q455* (on ENST00000355058; = p.Q444* on NM_003744.5) | Nonsense Mutation (SNP) | VAF 15/55 reads (27%) | catalogued as COSV99390206; called by muse, mutect2, varscan2
- OR10A6 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs145835770, COSV100564378, COSV59166205; called by muse, mutect2, varscan2
- OR2A2 | c.821C>G p.S274C | Missense Mutation (SNP) | VAF 70/235 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as COSV101286666, COSV101286679; called by muse, mutect2, varscan2
- OS9 | c.1645C>T p.R549C | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as rs1056923787, COSV99232514, COSV99233008; called by muse, mutect2, varscan2
- OSBP | c.748G>C p.E250Q | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.279); catalogued as COSV55661122, COSV99803275; called by muse, mutect2, varscan2
- PCDHGC4 | c.806C>T p.P269L | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.01); catalogued as COSV99341697; called by muse, mutect2, varscan2
- PPA1 | c.304G>T p.E102* | Nonsense Mutation (SNP) | VAF 11/57 reads (19%) | catalogued as COSV100949943, COSV64684445; called by muse, mutect2, varscan2
- RBFOX1 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 54/200 reads (27%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs755458164, COSV60948155; called by muse, mutect2, varscan2
- RICTOR | c.3227C>G p.S1076C | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.303); catalogued as COSV57120864, COSV99705530; called by muse, mutect2, varscan2
- RNF103 | c.831G>C p.M277I | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV99410331; called by muse, mutect2
- RNF148 | c.454G>A p.A152T | Missense Mutation (SNP) | VAF 94/329 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as rs200865337; called by muse, mutect2, varscan2
- SF3B5 | c.260G>C p.*87Sext*53 | Nonstop Mutation (SNP) | VAF 25/175 reads (14%) | catalogued as COSV100845571; called by muse, mutect2, varscan2
- SFTPA1 | c.391A>G p.I131V | Missense Mutation (SNP) | VAF 29/222 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV100957129; called by muse, mutect2, varscan2
- SHANK1 | c.460-2A>T p.X154_splice | Splice Site (SNP) | VAF 64/138 reads (46%) | catalogued as COSV99521754; called by muse, mutect2, varscan2
- SLC38A1 | c.1355G>C p.R452T | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV101284162, COSV101284258; called by muse, mutect2, varscan2
- SPN | c.838C>T p.R280W | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.576); catalogued as rs763281424, COSV64070855; called by muse, mutect2, varscan2
- SPTA1 | c.5014G>T p.D1672Y | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.515); catalogued as COSV100935356, COSV63752374; called by muse, mutect2, varscan2
- SRP68 | c.405G>C p.W135C | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); catalogued as COSV57162544, COSV57164265; called by muse, mutect2, varscan2
- TCF4 | c.1788G>C p.K596N | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.987); catalogued as COSV100610659; called by muse, mutect2, varscan2
- THBS4 | c.2638T>C p.S880P | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100644382; called by muse, mutect2, varscan2
- TICRR | c.5009C>T p.S1670F | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99178976; called by muse, mutect2, varscan2
- TICRR | c.5461G>C p.E1821Q | Missense Mutation (SNP) | VAF 24/186 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.892); catalogued as COSV99178984; called by muse, mutect2, varscan2
- TTN | c.79062C>A p.N26354K (on ENST00000591111; = p.N18930K on NM_003319.4) | Missense Mutation (SNP) | VAF 8/23 reads (35%) | PolyPhen benign (0.007); catalogued as COSV100623904; called by muse, mutect2, varscan2
- TUSC3 | c.515G>A p.G172E | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101142336; called by muse, mutect2, varscan2
- TXNDC8 | c.83C>G p.S28C | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.315); catalogued as COSV65725747; called by muse, mutect2, varscan2
- ZNF418 | c.1426C>G p.H476D | Missense Mutation (SNP) | VAF 50/136 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101268979; called by muse, mutect2, varscan2
- ZNRF3 | c.1880C>G p.S627C (on ENST00000544604 / NM_001206998.2; = p.S527C on NM_032173.3) | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.804); catalogued as rs746765538, COSV100238808; called by muse, mutect2, varscan2
- TOR4A | c.1254del p.T419Rfs*2 | Frame Shift Del (DEL) | VAF 4/14 reads (29%) | called by mutect2, varscan2
- ABCC1 | c.2508C>T p.D836= | Silent (SNP) | VAF 5/48 reads (10%) | catalogued as rs374092475; called by muse, mutect2, varscan2
- ANK1 | c.766C>A p.R256= | Silent (SNP) | VAF 25/97 reads (26%) | catalogued as COSV55878545, COSV99226343; called by muse, mutect2, varscan2
- ANO1 | c.195C>T p.I65= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV100304343; called by muse, mutect2, varscan2
- CAMK2A | c.327G>A p.E109= | Silent (SNP) | VAF 17/55 reads (31%) | catalogued as rs1287121256, COSV100804642; called by muse, mutect2, varscan2
- CGN | c.345G>A p.S115= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs370327717; called by muse, mutect2, varscan2
- CLCN7 | c.417C>T p.L139= | Silent (SNP) | VAF 19/74 reads (26%) | catalogued as rs1285794775, COSV99247550; called by muse, mutect2, varscan2
- CLDN9 | c.108C>T p.I36= | Silent (SNP) | VAF 20/116 reads (17%) | catalogued as rs200336281, COSV60910440; called by muse, mutect2, varscan2
- CTSO | c.405C>T p.F135= | Silent (SNP) | VAF 17/109 reads (16%) | catalogued as COSV101467874; called by muse, mutect2, varscan2
- DIAPH2 | c.516G>C p.S172= | Silent (SNP) | VAF 17/31 reads (55%) | catalogued as COSV100233640, COSV100234479, COSV61280146; called by muse, mutect2, varscan2
- DNAH3 | c.6816C>G p.V2272= | Silent (SNP) | VAF 9/70 reads (13%) | catalogued as COSV54528527; called by muse, mutect2, varscan2
- FRG2C | c.702T>C p.Y234= | Silent (SNP) | VAF 14/134 reads (10%) | called by muse, mutect2
- H3C11 | c.126C>T p.Y42= | Silent (SNP) | VAF 36/120 reads (30%) | catalogued as COSV100138023; called by muse, mutect2, varscan2
- HTR1A | c.456C>T p.R152= | Silent (SNP) | VAF 24/112 reads (21%) | catalogued as COSV60500672; called by muse, mutect2, varscan2
- ILVBL | c.1587C>T p.I529= | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as rs537834156, COSV99655029; called by muse, mutect2, varscan2
- ITLN1 | c.138C>T p.D46= | Silent (SNP) | VAF 21/60 reads (35%) | catalogued as rs373845227; called by muse, mutect2, varscan2
- KCNK9 | c.867C>T p.D289= | Silent (SNP) | VAF 14/94 reads (15%) | catalogued as rs1327148194, COSV57289341; called by muse, mutect2, varscan2
- MAST3 | c.198G>A p.S66= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as rs370509186; called by muse, mutect2, varscan2
- MEF2D | c.360C>A p.A120= | Silent (SNP) | VAF 39/98 reads (40%) | catalogued as COSV100560247; called by muse, mutect2, varscan2
- PDE6C | c.1995C>T p.F665= | Silent (SNP) | VAF 61/194 reads (31%) | catalogued as rs764148537, COSV101008820, COSV65116719; called by muse, mutect2, varscan2
- PRRX1 | c.483C>T p.N161= | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as COSV53411899; called by muse, mutect2, varscan2
- RRP12 | c.2424C>G p.L808= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV100213377; called by muse, mutect2, varscan2
- SLC4A11 | c.1188C>T p.L396= | Silent (SNP) | VAF 12/123 reads (10%) | catalogued as rs895758008, COSV101196106, COSV66260741; called by muse, mutect2
- SORCS3 | c.2172T>A p.R724= | Silent (SNP) | VAF 10/82 reads (12%) | catalogued as COSV100863736; called by muse, varscan2
- SULF2 | c.93G>C p.L31= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as COSV100737358, COSV63419386; called by muse, mutect2, varscan2
- TRANK1 | c.8343A>G p.E2781= | Silent (SNP) | VAF 39/106 reads (37%) | catalogued as COSV100084206; called by muse, mutect2, varscan2
- VWA2 | c.1296T>C p.R432= | Silent (SNP) | VAF 14/114 reads (12%) | catalogued as COSV100073889; called by muse, mutect2, varscan2
- DCHS2 | n.6263C>T | RNA (SNP) | VAF 19/92 reads (21%) | catalogued as COSV100602348; called by muse, mutect2, varscan2
